FM case AD12899 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/90a53e14-058c-40fe-983e-8b493deffab3

Female, 38.6 years: Glioblastoma (ICD-O-3 9440/3) of the nervous system; metastasis biopsied or resected from the brain. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
